Gene-level copy-number profile of tumor specimen TCGA-EO-A1Y8-01A from TCGA case TCGA-EO-A1Y8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-EO-A1Y8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.c565d919-87e8-4450-8103-c2a375f30acc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A1Y8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e85eaca9-d3d7-47fa-bd3d-9be74cd2f929

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 312; copy number 2: 4,192; copy number 3: 11,688; copy number 4: 35,433; copy number 5: 3,649; copy number 6: 916; copy number 7: 295; copy number 8: 157; copy number 9: 628; copy number 10: 1,016; copy number 11: 416; copy number 12: 567; copy number 13: 202; copy number 14: 128; copy number 15: 92; copy number 16: 45; copy number 17: 7; copy number 18: 34; copy number 20: 7; copy number 25: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A1Y8-01A-11D-A160-01): tumor purity 0.82, ploidy 4.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,167 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:47,849,555–48,504,826, 29 genes, copy number 11: MIR1226, MAP4, Y_RNA, VPS26BP1, AC124916.2, RN7SL664P, AC124916.1, CDC25A, SNRPFP4, RNU7-128P, NDUFB1P1, MIR4443, CAMP, ZNF589, MRPS18AP1, Y_RNA, NME6, FCF1P2, SPINK8, MIR2115, FBXW12, RN7SL321P, PLXNB1, CCDC51, TMA7, AC134772.1, ATRIP, TREX1, SHISA5.
- chr5:2,184,710–41,870,425, 563 genes, copy number 9–20 (within-gene range 2–32) (broad region; genes not listed).
- chr7:102,264,706–103,074,843, 39 genes, copy number 11 (within-gene range 5–11): AC005088.1, SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O, AC073517.1, ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2, RASA4DP, AC105052.5, FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17.
- chr7:155,611,231–159,233,377, 53 genes, copy number 10: AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:150,584–21,913,690, 481 genes, copy number 9–25 (broad region; genes not listed).
- chr8:41,261,962–145,066,685, 1,613 genes, copy number 9–15 (broad region; genes not listed).
- chr9:35,657,751–35,790,432, 16 genes, copy number 16–17 (within-gene range 5–17): RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1.
- chr19:8,806,170–8,981,342, 5 genes, copy number 10 (within-gene range 2–10): ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16.
- chr19:9,518,150–14,471,867, 295 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr19:17,794,828–19,192,158, 73 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 312. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
